Surgical pathology report (de-identified scan), TCGA case TCGA-EP-A2KB, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-EP-A2KB-01A (Primary Tumor).

Final Surgical Pathology Report

ICD-0-3

carcinoma, hepatocellular, NOS

8170/3

Site: liver C22.0

8/24/14

Procedure:

Diagnosis

Liver, segment 6, resection: Hepatocellular carcinoma arising in micronodular cirrhosis, completely excised

Microscopic Description:

Histologic type: Hepatocellular carcinoma

Histologic grade: 2 (Edmundson and Steiner, Cancer 7:462, 1954); 1 (WHO)

Tumor size: 2.4 cm

Vascular invasion: Absent

Margins of resection: Negative for malignancy

pTNM stage: T1

Adjacent liver: Micronodular cirrhosis with moderate chronic inflammation and moderate to marked .mixed hepatocellular steatosis.

Specimen

Liver segment 6

Clinical Information

Hepatocellular cancer

Gross Description

The specimen is received unfixed labeled liver segment 6 and consists of a piece of red tissue measuring 7 by 5.5 x 4 cm. The specimen has been incised prior to receipt showing cirrhotic liver and a roughly spherical subcapsular tumor. The tumor is gold colored and measures 2.4 cm in diameter. The margin of the specimen is inked. A portion of specimen is taken for research purposes. Sections after fixation. RS7

Source: NCI Genomic Data Commons file 108b98ab-722f-43b5-b8db-7413ff01e93c (TCGA-EP-A2KB.DF650AE0-E9E8-48A7-8D39-88A3F7EC2AC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).